CCDI case PBCCKS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/fb92eccc-25ff-41ca-950e-3999ac95796c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Leydig cell tumor, NOS: ICD-O-3 morphology code: 8650/1; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 5.1 years (1,854 days).

Biospecimens (3 samples)
- Samples 0DSEKE, 0DSEL3 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSEKS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
